Somatic mutation profile of tumor specimen 0DQSTY from CCDI case PBCFNS, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 6.1 years (2,243 days).
Specimen 0DQSTY: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d5e32128-9893-4348-996e-9cf1ed8c3251.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DQSUS (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/cbcd9db3-3b0a-4499-b9a2-7188d208bc24

The open-access MAF lists 43 somatic variants for this specimen: 22 protein-altering or splice-affecting, 9 silent, 12 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 21, Silent 9, Intron 6, RNA 2, 5'UTR 2, 3'UTR 1, Splice Region 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCC11 | c.851C>A p.T284N | Missense Mutation (SNP) | VAF 59/441 reads (13%) | SIFT tolerated (0.16); PolyPhen benign (0.007); catalogued as rs1439424893; called by muse, mutect2, varscan2
- CC2D2B | c.754G>T p.V252L | Missense Mutation (SNP) | VAF 55/327 reads (17%) | SIFT tolerated (0.64); PolyPhen benign (0.015); catalogued as rs1459698270; called by muse, mutect2, varscan2
- COL4A5 | c.3005C>T p.P1002L | Missense Mutation (SNP) | VAF 13/391 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.658); catalogued as COSV100086809, COSV100087200; called by muse, mutect2
- CROCC | c.4025G>A p.R1342Q | Missense Mutation (SNP) | VAF 38/792 reads (5%) | SIFT deleterious (0.05); PolyPhen benign (0.003); catalogued as rs748070984, COSV65014403; called by muse, mutect2
- FLNA | c.4981G>A p.G1661S (on ENST00000369850 / NM_001110556.2; = p.G1653S on NM_001456.3) | Missense Mutation (SNP) | VAF 62/298 reads (21%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.658); catalogued as rs1402204338; called by muse, mutect2, varscan2
- GLYATL2 | c.306G>T p.Q102H | Missense Mutation (SNP) | VAF 20/346 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.828); catalogued as COSV54851326; called by muse, mutect2
- INTS1 | c.2719G>A p.V907M | Missense Mutation (SNP) | VAF 180/1109 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs758053978; called by muse, mutect2, varscan2
- LRRC8C | c.791G>A p.R264H | Missense Mutation (SNP) | VAF 37/677 reads (5%) | SIFT tolerated (0.55); PolyPhen possibly damaging (0.511); catalogued as rs377556616; called by muse, mutect2
- LRRK2 | c.1023G>T p.E341D | Missense Mutation (SNP) | VAF 59/345 reads (17%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as rs1314382598; called by muse, mutect2, varscan2
- MTHFS | c.120G>A p.V40= | Splice Region (SNP) | VAF 13/330 reads (4%) | catalogued as rs1447303315; called by muse, mutect2
- OR12D2 | c.386G>A p.R129H | Missense Mutation (SNP) | VAF 99/512 reads (19%) | SIFT tolerated (0.55); PolyPhen benign (0.005); catalogued as rs552058342, COSV65830026; called by muse, mutect2, varscan2
- PTPN14 | c.734T>C p.I245T | Missense Mutation (SNP) | VAF 14/365 reads (4%) | SIFT tolerated (0.12); PolyPhen benign (0.037); catalogued as rs1242588140; called by muse, mutect2
- SAP18 | c.454C>G p.P152A (on ENST00000607003; = p.P171A on NM_005870.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 31/248 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.468); catalogued as COSV66822972; called by muse, mutect2, varscan2
- TBR1 | c.823G>T p.G275C | Missense Mutation (SNP) | VAF 205/459 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67417745; called by muse, mutect2, varscan2
- COBL | c.2383C>T p.P795S | Missense Mutation (SNP) | VAF 20/786 reads (3%) | SIFT tolerated (0.4); PolyPhen benign (0.001); called by muse, mutect2
- DNAJC8 | c.725T>C p.L242P | Missense Mutation (SNP) | VAF 103/469 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); called by muse, mutect2, varscan2
- MIB1 | c.254G>C p.C85S | Missense Mutation (SNP) | VAF 19/528 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.784); called by muse, mutect2
- MYH2 | c.1903G>T p.A635S | Missense Mutation (SNP) | VAF 14/158 reads (9%) | SIFT tolerated (0.66); PolyPhen benign (0.001); called by muse, mutect2
- NBPF26 | c.2324G>T p.G775V (on ENST00000620612; = p.G513V on NM_001351372.1) | Missense Mutation (SNP) | VAF 20/120 reads (17%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- PTAR1 | c.647T>C p.L216P | Missense Mutation (SNP) | VAF 65/436 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); called by muse, mutect2, varscan2
- SLC25A30 | c.476G>A p.R159K | Missense Mutation (SNP) | VAF 29/223 reads (13%) | SIFT tolerated (0.2); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- TRIM37 | c.1228C>A p.Q410K | Missense Mutation (SNP) | VAF 62/494 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.791); called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.7084C>A p.R2362= | Silent (SNP) | VAF 49/760 reads (6%) | catalogued as COSV99783811; called by muse, mutect2
- CYP3A4 | c.690C>T p.I230= | Silent (SNP) | VAF 26/387 reads (7%) | called by muse, mutect2
- DRD5 | c.499T>C p.L167= | Silent (SNP) | VAF 91/482 reads (19%) | catalogued as COSV58577101; called by muse, mutect2, varscan2
- DTX2 | c.582C>T p.V194= | Silent (SNP) | VAF 128/805 reads (16%) | catalogued as rs1357696043, COSV56862665; called by muse, varscan2
- GABBR2 | c.702C>T p.N234= | Silent (SNP) | VAF 94/1428 reads (7%) | catalogued as rs759372813, COSV52316761; called by muse, mutect2
- KASH5 | c.816C>T p.A272= | Silent (SNP) | VAF 42/188 reads (22%) | catalogued as rs369003961; called by muse, mutect2, varscan2
- MUC5B | c.3282C>T p.A1094= | Silent (SNP) | VAF 58/640 reads (9%) | catalogued as rs200721558; called by muse, mutect2
- UBE2J1 | c.57G>T p.A19= | Silent (SNP) | VAF 43/273 reads (16%) | catalogued as COSV101470263; called by muse, mutect2, varscan2
- ZNF519 | c.1243A>C p.R415= | Silent (SNP) | VAF 10/235 reads (4%) | called by muse, mutect2
- AC235097.1 | n.223G>A | RNA (SNP) | VAF 137/609 reads (22%) | called by muse, mutect2
- ARF1 | c.*4C>T | 3'UTR (SNP) | VAF 35/524 reads (7%) | catalogued as rs374058258; called by muse, mutect2
- ARHGAP44 | c.-36C>A | 5'UTR (SNP) | VAF 13/125 reads (10%) | called by muse, mutect2
- CRHR1 | c.796+11C>T | Intron (SNP) | VAF 37/713 reads (5%) | catalogued as rs1360465447; called by muse, mutect2
- DAZAP2 | c.133-63T>C | Intron (SNP) | VAF 8/140 reads (6%) | called by muse, mutect2
- DCHS2 | n.276G>T | RNA (SNP) | VAF 19/544 reads (3%) | catalogued as COSV100250549; called by muse, mutect2
- KIF5A | c.2024-100T>A | Intron (SNP) | VAF 10/90 reads (11%) | catalogued as rs1442284594; called by muse, mutect2, varscan2
- KLC2 | c.1785+37C>T | Intron (SNP) | VAF 21/251 reads (8%) | catalogued as rs778863040, COSV57583312; called by muse, mutect2
- MAPT | c.1732+2371C>A | Intron (SNP) | VAF 33/582 reads (6%) | catalogued as rs866670849; called by muse, mutect2
- MCM4 | c.-24dup | 5'UTR (INS) | VAF 83/190 reads (44%) | called by mutect2, pindel, varscan2
- OLFML3 | c.115-57C>G | Intron (SNP) | VAF 14/182 reads (8%) | called by muse, mutect2
- PGLS | chr19:17511631 G>A | 5'Flank (SNP) | VAF 16/119 reads (13%) | catalogued as rs909613562; called by muse, mutect2, varscan2
